Somatic mutation profile of tumor specimen MMRF_1930_1_BM_CD138pos (aliquot MMRF_1930_1_BM_CD138pos_T1_KHS5U_L08843) from MMRF case MMRF_1930, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.6 years (21,040 days).
Specimen MMRF_1930_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6a864e4-4619-406f-8dc4-d5eba5741bc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1930_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1930_1_PB_WBC_C2_KHS5U_L08791; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af1fb624-1357-4409-9b34-3480bc59d3ba

The open-access MAF lists 92 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 22, Silent 11, Intron 11, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, 5'UTR 2, RNA 2, 3'Flank 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148295854, COSV99695926; called by muse, mutect2
- BRWD1 | c.6926T>A p.L2309* | Nonsense Mutation (SNP) | VAF 28/46 reads (61%) | catalogued as rs768122638, COSV59000653; called by muse, mutect2, varscan2
- CCDC168 | c.14263C>T p.P4755S | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV99079850; called by muse, mutect2, varscan2
- CLTCL1 | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as rs782233393, COSV54241093; called by muse, mutect2, varscan2
- HTR1F | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 19/525 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV60390972; called by muse, mutect2
- IGLV3-1 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs144850905; called by muse, mutect2, varscan2
- IGLV3-1 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT tolerated (0.21); PolyPhen benign (0.445); catalogued as rs374050608; called by muse, varscan2
- KMT2C | c.10886T>C p.I3629T | Missense Mutation (SNP) | VAF 102/367 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1358618609; called by muse, mutect2, varscan2
- KRT23 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs754984346; called by muse, mutect2, varscan2
- MTO1 | c.1425G>C p.L475F (on ENST00000370300 / NM_133645.3; = p.L450F on NM_012123.4) | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1272527669; called by muse, mutect2
- MXRA5 | c.6530G>A p.R2177H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773254958, COSV54243733; called by muse, mutect2, varscan2
- NPSR1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs114775765; called by muse, mutect2, varscan2
- PCDHA9 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.631); catalogued as COSV65323597; called by muse, mutect2
- TENM2 | c.2974C>T p.R992C (on ENST00000518659 / NM_001122679.2; = p.R760C on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs373290432; called by muse, mutect2
- TENM3 | c.7769C>T p.T2590M | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101305083; called by muse, mutect2
- THBD | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV101001920; called by muse, mutect2
- WDR87 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs763392800, COSV58193343; called by muse, mutect2
- ZNF292 | c.3524A>G p.N1175S | Missense Mutation (SNP) | VAF 129/241 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371800584; called by muse, mutect2, varscan2
- CATIP | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CXorf66 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 167/176 reads (95%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DUSP1 | c.641T>C p.F214S | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP400 | c.3401C>T p.S1134L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR1A | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 142/228 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGHV1-69D | c.237C>G p.Y79* | Nonsense Mutation (SNP) | VAF 74/88 reads (84%) | called by muse, mutect2, varscan2
- KCNN4 | c.441A>C p.Q147H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2
- MUC13 | c.636A>T p.K212N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PHYH | c.559_566dup p.I189Mfs*32 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, varscan2
- PIGZ | c.672C>A p.F224L | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.394); called by muse, mutect2
- PP2D1 | c.852del p.A285Pfs*13 | Frame Shift Del (DEL) | VAF 99/334 reads (30%) | called by mutect2, pindel, varscan2
- RBM15 | c.399T>A p.N133K | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RBM6 | c.3081A>C p.E1027D | Missense Mutation (SNP) | VAF 17/534 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- SEC24B | c.3361T>G p.L1121V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SLC9A8 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- STXBP5 | c.249-2A>T p.X83_splice | Splice Site (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- TIGD3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TTC30B | c.1127T>G p.F376C | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- TTC39A | c.1107_1137del p.W369* (on ENST00000447632 / NM_001297665.1; = p.W334* on NM_001080494.3) | Frame Shift Del (DEL) | VAF 50/216 reads (23%) | called by mutect2, pindel
- UNC80 | c.9117-1G>A p.X3039_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- ZBTB44 | c.973del p.Q325Kfs*7 | Frame Shift Del (DEL) | VAF 53/259 reads (20%) | called by mutect2, pindel, varscan2
- ZMYM4 | c.1074A>C p.K358N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF330 | c.191T>C p.L64S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLEC16A | c.2874G>A p.T958= | Silent (SNP) | VAF 93/221 reads (42%) | catalogued as rs61744091, COSV55488459, COSV55491648; called by muse, mutect2, varscan2
- DLGAP1 | c.2352G>T p.V784= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- FZD9 | c.678C>T p.R226= | Silent (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- GLI2 | c.1446C>T p.G482= (on ENST00000361492 / NM_001374353.1; = p.G499= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as rs1456279701; called by muse, mutect2, varscan2
- NR1H2 | c.273G>T p.G91= | Silent (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2
- PSD2 | c.309G>A p.V103= | Silent (SNP) | VAF 69/200 reads (35%) | called by muse, mutect2, varscan2
- SFMBT1 | c.1695T>G p.S565= | Silent (SNP) | VAF 56/81 reads (69%) | called by muse, mutect2, varscan2
- TBC1D8B | c.483C>T p.T161= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs1569450337, COSV99344993; called by muse, mutect2, varscan2
- TMEM126A | c.165A>G p.R55= | Silent (SNP) | VAF 34/486 reads (7%) | called by muse, mutect2
- TRAF5 | c.522T>C p.D174= | Silent (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- TTC32 | c.87A>G p.A29= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV61267855; called by muse, mutect2, varscan2
- ACSS3 | c.*4448T>G | 3'UTR (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- ADAMTS2 | c.3089-24G>A | Intron (SNP) | VAF 18/138 reads (13%) | catalogued as rs913554063, COSV99280731; called by muse, mutect2, varscan2
- ADRB1 | c.*382G>A | 3'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- AP000769.5 | chr11:65499813 G>C | 5'Flank (SNP) | VAF 41/65 reads (63%) | catalogued as rs1025235426; called by muse, mutect2, varscan2
- ARHGAP1 | c.*1392T>C | 3'UTR (SNP) | VAF 19/152 reads (13%) | called by muse, mutect2, varscan2
- ATP2B3 | c.*2631G>T | 3'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- C16orf86 | c.554-37G>A | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as rs767334699; called by muse, mutect2, varscan2
- CACNA1I | c.6027+184C>T | Intron (SNP) | VAF 8/58 reads (14%) | catalogued as rs374870355; called by muse, mutect2, varscan2
- CBX7 | c.*880_*894del | 3'UTR (DEL) | VAF 40/78 reads (51%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.*800C>T | 3'UTR (SNP) | VAF 82/129 reads (64%) | called by muse, mutect2, varscan2
- CYP2U1 | c.*2424C>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- DBF4P1 | n.1655G>A | RNA (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- DMD | c.2292+455T>G | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- DPPA4 | c.*632A>C | 3'UTR (SNP) | VAF 43/60 reads (72%) | called by muse, mutect2, varscan2
- DTX2 | c.1230+770C>T | Intron (SNP) | VAF 6/77 reads (8%) | catalogued as rs2462258; called by muse, mutect2
- EDIL3 | c.1137+12044G>T | Intron (SNP) | VAF 13/54 reads (24%) | catalogued as rs955527349; called by muse, mutect2, varscan2
- FAM24B | chr10:122845923 G>T | 3'Flank (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100159054; called by muse, mutect2, varscan2
- G3BP1 | c.96-9A>G | Intron (SNP) | VAF 22/52 reads (42%) | catalogued as rs1370285177; called by muse, mutect2, varscan2
- GNB5 | c.*1743G>A | 3'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as rs1180536910; called by muse, mutect2, varscan2
- GNG12 | c.*1218A>C | 3'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- HAUS6P3 | n.871A>T | RNA (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- HIPK3 | c.*150T>A | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- HJURP | c.-32C>T | 5'UTR (SNP) | VAF 21/160 reads (13%) | catalogued as rs375557380; called by muse, mutect2, varscan2
- KCNJ18 | c.*164C>T | 3'UTR (SNP) | VAF 39/77 reads (51%) | catalogued as rs1305931283; called by muse, varscan2
- KCNV1 | chr8:109965221 C>G | 3'Flank (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- KMT2D | c.5468-43G>A | Intron (SNP) | VAF 77/174 reads (44%) | called by muse, mutect2, varscan2
- KREMEN2 | c.*113C>A | 3'UTR (SNP) | VAF 44/116 reads (38%) | catalogued as rs1430314282; called by muse, mutect2, varscan2
- LUZP2 | c.*1844A>T | 3'UTR (SNP) | VAF 7/169 reads (4%) | called by muse, mutect2
- LZTS3 | c.*236G>A | 3'UTR (SNP) | VAF 26/40 reads (65%) | called by muse, mutect2, varscan2
- MIDEAS | c.*3851T>A | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- MIPOL1 | c.1263-1090C>T | Intron (SNP) | VAF 29/197 reads (15%) | catalogued as rs1346404578; called by muse, mutect2, varscan2
- NXPE3 | c.-54A>T | 5'UTR (SNP) | VAF 34/667 reads (5%) | called by muse, mutect2
- PTPN1 | c.*916G>C | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- RGL4 | c.374-45C>A | Intron (SNP) | VAF 18/150 reads (12%) | called by muse, varscan2
- SLC2A3 | c.*462T>C | 3'UTR (SNP) | VAF 46/129 reads (36%) | called by muse, mutect2, varscan2
- SLC5A7 | c.*3070A>C | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- STK32A | c.*2271A>G | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- TNRC6A | c.*1690C>T | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- TTC30A | c.*1402G>A | 3'UTR (SNP) | VAF 14/110 reads (13%) | catalogued as rs897326450; called by muse, mutect2, varscan2
- ZFPL1 | c.408+14G>A | Intron (SNP) | VAF 84/271 reads (31%) | catalogued as rs201223069; called by muse, mutect2, varscan2
